Somatic mutation profile of tumor specimen TCGA-15-1446-01A (aliquot TCGA-15-1446-01A-01W-0611-08) from TCGA case TCGA-15-1446, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.7 years (20,355 days).
Specimen TCGA-15-1446-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b461643b-8b32-409d-b9ed-2cda5f996f3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-15-1446-10A (Blood Derived Normal), aliquot TCGA-15-1446-10A-01W-0612-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b423aa19-49ba-435c-9e91-339069c75ed2

The open-access MAF lists 91 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 23, Nonsense Mutation 7, Splice Site 2, Splice Region 2, 3'UTR 1, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1D | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV101062880; called by muse, mutect2
- C3orf20 | c.2652G>T p.E884D | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99513343; called by muse, mutect2, varscan2
- CDK12 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV71002814; called by muse, mutect2
- COL14A1 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV99917961; called by muse, mutect2, varscan2
- COL17A1 | c.873G>T p.L291F | Missense Mutation (SNP) | VAF 46/670 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100793035; called by muse, mutect2
- CORO2B | c.486C>A p.V162= | Splice Region (SNP) | VAF 6/129 reads (5%) | catalogued as COSV99962871; called by muse, mutect2
- CPD | c.3969C>A p.C1323* | Nonsense Mutation (SNP) | VAF 9/140 reads (6%) | catalogued as COSV56717103, COSV99852433; called by muse, mutect2
- DENND4C | c.2666G>T p.R889L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100991200, COSV66822724; called by muse, mutect2
- DGKI | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as COSV99932346; called by muse, mutect2, varscan2
- DIDO1 | c.1702C>A p.P568T | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as COSV56622809, COSV99824642; called by muse, varscan2
- DSCAML1 | c.4034C>A p.A1345D (on ENST00000321322; = p.A1285D on NM_020693.4) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV100354513; called by muse, mutect2, varscan2
- DST | c.2722G>T p.D908Y (on ENST00000361203 / NM_001374722.1; = p.D582Y on NM_001723.6) | Missense Mutation (SNP) | VAF 14/395 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99749333; called by muse, mutect2
- EGR2 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 27/555 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.133); catalogued as COSV99653971; called by muse, mutect2
- FAT4 | c.3856C>A p.Q1286K | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.943); catalogued as COSV101271824, COSV101272886; called by muse, mutect2
- FGD1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100910779; called by muse, mutect2
- FITM1 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as COSV99246001; called by muse, mutect2, varscan2
- GPX2 | c.141C>A p.F47L | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99962013; called by muse, mutect2
- INPP1 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100487086; called by muse, mutect2
- IQUB | c.867+1G>A p.X289_splice | Splice Site (SNP) | VAF 21/213 reads (10%) | catalogued as COSV100226727; called by muse, mutect2, varscan2
- KANK2 | c.1823C>T p.P608L (on ENST00000586659 / NM_001379562.1; = p.P616L on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/476 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV100763001; called by muse, mutect2
- KAT14 | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100890028; called by muse, mutect2
- KCNH1 | c.2661C>A p.S887R (on ENST00000271751 / NM_172362.3; = p.S860R on NM_002238.4) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.134); catalogued as COSV99657190; called by muse, varscan2
- KPNA6 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 14/353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101012433; called by muse, mutect2
- LHCGR | c.1317C>A p.C439* | Nonsense Mutation (SNP) | VAF 48/676 reads (7%) | catalogued as rs1181883562, COSV99683147; called by muse, mutect2
- LMTK2 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.443); catalogued as COSV99805960; called by muse, mutect2
- LYST | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 30/309 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV67703322; called by muse, mutect2
- METTL14 | c.730G>T p.G244* | Nonsense Mutation (SNP) | VAF 11/141 reads (8%) | catalogued as COSV101183345; called by muse, mutect2
- MGA | c.1131C>A p.F377L | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV99578434; called by muse, mutect2
- NCAN | c.3535G>A p.A1179T | Missense Mutation (SNP) | VAF 483/1877 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs760380292, COSV53056800; called by muse, mutect2, varscan2
- NCL | c.1759A>G p.T587A | Missense Mutation (SNP) | VAF 264/766 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs113883398, COSV100502217; called by muse, mutect2, varscan2
- NUP160 | c.1104C>T p.F368= | Splice Region (SNP) | VAF 35/293 reads (12%) | catalogued as COSV101021267; called by muse, varscan2
- OAS2 | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660013; called by muse, mutect2
- OR10H4 | c.610G>C p.V204L | Missense Mutation (SNP) | VAF 44/582 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.075); catalogued as COSV100437663; called by muse, mutect2
- OR11H6 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59644213; called by muse, mutect2, varscan2
- P2RY6 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV100573841; called by muse, mutect2
- PCDHB2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs782682660, COSV99164149, COSV99166535; called by muse, mutect2
- PDHA1 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.131); catalogued as COSV100133982; called by muse, mutect2
- PDZD2 | c.8130G>T p.Q2710H | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99223598; called by muse, mutect2
- PLA2G15 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 173/582 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs372057867; called by muse, mutect2, varscan2
- PLEKHA7 | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs533703040, COSV63046143; called by muse, mutect2, varscan2
- PRKAG1 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 20/630 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV100304862; called by muse, mutect2
- PRKCH | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 316/1200 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs55818778, COSV100272763; called by muse, mutect2, varscan2
- PRKD1 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 48/732 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100119243; called by muse, mutect2
- QSER1 | c.2310G>T p.M770I (on ENST00000399302; = p.M899I on NM_001076786.3) | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV101234629; called by muse, mutect2
- RALGAPA2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV99173130; called by muse, mutect2, varscan2
- RPL13A | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV54526065, COSV99569318; called by muse, mutect2, varscan2
- SLC29A1 | c.981C>A p.Y327* | Nonsense Mutation (SNP) | VAF 29/949 reads (3%) | catalogued as COSV100505558; called by muse, mutect2
- STAT2 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV100028583; called by muse, varscan2
- SYNE1 | c.17300C>A p.A5767D (on ENST00000367255 / NM_182961.4; = p.A5696D on NM_033071.3) | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV99552528; called by muse, mutect2
- SYNE2 | c.19638G>T p.K6546N | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100646634; called by muse, mutect2
- TNIK | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1330784130, COSV99454139; called by muse, mutect2, varscan2
- UGT2B4 | c.185T>G p.I62S | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV100522185; called by muse, mutect2, varscan2
- USP28 | c.893C>A p.T298N | Missense Mutation (SNP) | VAF 18/489 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV99134465; called by muse, mutect2
- WSCD2 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs965481498, COSV54586388; called by muse, mutect2
- XCL2 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs536437816, COSV63194760; called by muse, mutect2, varscan2
- ZBTB38 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 12/182 reads (7%) | catalogued as COSV100375246; called by muse, mutect2
- ZBTB41 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100962807; called by muse, mutect2, varscan2
- ZGRF1 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.234); catalogued as COSV100005309; called by muse, mutect2
- ZNF468 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 19/561 reads (3%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.997); catalogued as COSV99700320; called by muse, mutect2
- ACACA | c.2730C>A p.F910L | Missense Mutation (SNP) | VAF 24/846 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- DYNC1I1 | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 23/712 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- ENPP3 | c.174C>A p.C58* | Nonsense Mutation (SNP) | VAF 45/327 reads (14%) | called by mutect2, varscan2
- PFKL | c.1814_1815insTGTGTGTGCAGGCTGCTGTCCACTGTGCCCTGGGG p.K605Nfs*19 | Frame Shift Ins (INS) | VAF 74/82 reads (90%) | called by mutect2, varscan2*
- PFN1 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UBTF | c.474+1G>A p.X158_splice | Splice Site (SNP) | VAF 14/88 reads (16%) | called by mutect2, varscan2
- ABCA1 | c.6777C>T p.S2259= | Silent (SNP) | VAF 178/826 reads (22%) | catalogued as COSV101036473; called by muse, mutect2, varscan2
- ADAMTS12 | c.678G>A p.K226= | Silent (SNP) | VAF 16/375 reads (4%) | catalogued as COSV100710255, COSV61281859; called by muse, mutect2
- AHRR | c.765G>A p.P255= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs371473301; called by muse, mutect2, varscan2
- CACNA2D3 | c.762G>A p.P254= | Silent (SNP) | VAF 322/996 reads (32%) | catalogued as rs757954461, COSV55511572; called by muse, mutect2, varscan2
- CHRNA9 | c.321C>A p.I107= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV100038800; called by muse, mutect2
- DNAH8 | c.5670G>A p.Q1890= | Silent (SNP) | VAF 36/316 reads (11%) | catalogued as rs1398844654, COSV100543195; called by muse, varscan2
- FAM118B | c.663A>T p.G221= | Silent (SNP) | VAF 13/216 reads (6%) | catalogued as COSV100796817; called by muse, mutect2
- GRIN2B | c.2064C>T p.N688= | Silent (SNP) | VAF 34/351 reads (10%) | catalogued as rs748606750, COSV74206340; called by muse, mutect2, varscan2
- KDM2B | c.2352G>A p.K784= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs1555289424, COSV100997164; called by muse, mutect2, varscan2
- KRT15 | c.612C>T p.G204= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as rs577866815, COSV54180244; called by muse, mutect2
- METTL7A | c.345A>C p.R115= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV100153627; called by muse, varscan2
- NISCH | c.1884G>C p.R628= | Silent (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2
- NSUN2 | c.1779C>T p.S593= | Silent (SNP) | VAF 165/338 reads (49%) | catalogued as rs146819725; called by muse, mutect2, varscan2
- OR13C8 | c.342C>A p.I114= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100622920; called by muse, mutect2
- PRKAR1B | c.825G>A p.Q275= | Silent (SNP) | VAF 26/644 reads (4%) | catalogued as rs1158383268, COSV100816519; called by muse, mutect2
- PSMD7 | c.909C>T p.D303= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99542526, COSV99542540; called by muse, mutect2
- RAD50 | c.1017C>A p.L339= | Silent (SNP) | VAF 18/216 reads (8%) | catalogued as COSV54753126; called by muse, mutect2
- RYR1 | c.13845G>A p.G4615= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100614368; called by muse, mutect2
- SH3RF1 | c.1587C>A p.T529= | Silent (SNP) | VAF 9/149 reads (6%) | catalogued as COSV99498614; called by muse, mutect2
- SLC17A8 | c.1722G>A p.E574= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100035160; called by muse, mutect2, varscan2
- TMC5 | c.1116G>A p.Q372= (on ENST00000396229 / NM_001105248.1; = p.Q126= on NM_024780.5) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs930670474, COSV99572156; called by muse, mutect2
- VRTN | c.471C>T p.F157= | Silent (SNP) | VAF 71/153 reads (46%) | catalogued as rs367591527; called by muse, mutect2, varscan2
- ZNF609 | c.666G>A p.A222= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs569849172, COSV58582554; called by muse, mutect2, varscan2
- CDK20 | c.*349C>A | 3'UTR (SNP) | VAF 24/327 reads (7%) | catalogued as COSV100307961; called by muse, mutect2
- GDPD4 | c.1540+15G>A | Intron (SNP) | VAF 55/129 reads (43%) | catalogued as rs762300728, COSV100265009; called by muse, mutect2, varscan2
- KIR3DX1 | n.458T>G | RNA (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99682923; called by muse, mutect2
